Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91E, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91E-01A (Primary Tumor).

[page 1 of 2]
Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

1 - Biopsy of the peritoneum from the mesocolon root:
Absence of neoplasia.

2 - Gallbladder:
Chronic cholecystitis.

3 - Lymph node from chain 8p:
Absence of neoplasia: (0/1).

4 - "Part of hepatic segment III (hepatic margin):
Absence of neoplasia.

5 - Product of gastroduodenectomy, retroperitoneal lymphadenectomy and hepatic hilus:

- Adenocarcinoma, characterized by:
- Histologic pattern(s) observed: solid
- Histologic grade III - poorly differentiated
- Laurén's classification: intestinal type
- Measure of the longest axis of the tumor: 9.5 cm
- Ulceration: present
- Compromise of adjacent adipose tissue
- Type of tumor invasion: expansive
- Inflammatory reaction: moderate
- Proximal margin: uninvolved by neoplasia
- Distal margin: uninvolved by neoplasia
- Neural infiltration: present
- Lymphatic vascular invasion: not detected
- Sanguineous vascular invasion: not detected

- Mesenteric lymph nodes in adjacent fat:
Absence of neoplasia: (0/8)

Lymph nodes from the lesser curvature:
Absence of neoplasia: (0/17)

Lymph nodes from the greater curvature:
Absence of neoplasia: (0/4)

Epiplon:
Absence of neoplasia.

Pancreas with neoplastic infiltration only in the adjacent tissues

Per TSS, TCGA tumor is
100% tubular

case ICD O-3
Adenocarcinoma, intestinal
type 8144/3

path Adenocarcinoma, tubular
8211/3

Date: Maxine antrum
9/20/14 8/11/14

Per TSS Dx discrepancy form.
TCGA tumor is 100% tubular.

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Solid Adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	100% Tubular	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case was reviewed based on Top Slide to be sent to BCR	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file d5f5995b-db05-4827-a7e0-47798675d408 (TCGA-VQ-A91E.ADDB7A5E-7DBF-4A68-93CF-806C0641113D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).